Somatic mutation profile of tumor specimen C3L-00605-01 (aliquot CPT0063890006) from CPTAC case C3L-00605, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.7 years (26,936 days).
Specimen C3L-00605-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88d42b6e-8ec6-49c4-a9e9-393d330f9c7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00605-31 (Blood Derived Normal), aliquot CPT0065340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df5883ba-af5f-4995-ad79-f59948383046

The open-access MAF lists 104 somatic variants for this specimen: 80 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 13, Intron 9, Nonsense Mutation 7, Frame Shift Ins 5, Frame Shift Del 2, Splice Site 2, 5'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AF196969.1 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 75/366 reads (20%) | catalogued as rs587783613, CM001136; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 81/375 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 89/424 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM033666, COSV64288954, COSV64292660; called by muse, varscan2
- PTEN | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 228/460 reads (50%) | catalogued as rs786204928, CM992426, COSV64292229; ClinVar: pathogenic; called by muse, varscan2
- ABCB4 | c.3716G>A p.R1239H (on ENST00000265723 / NM_018849.3; = p.R1232H on NM_000443.4) | Missense Mutation (SNP) | VAF 22/716 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1160711086; called by muse, mutect2
- ACVR2A | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs761274834; called by muse, mutect2, varscan2
- ADGRG4 | c.7073C>A p.T2358K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV54964865; called by muse, mutect2, varscan2
- ANKS1B | c.2060T>C p.V687A | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1171454724; called by muse, mutect2, varscan2
- ARFGAP1 | c.775-6G>A | Splice Region (SNP) | VAF 79/217 reads (36%) | catalogued as rs752877009; called by muse, mutect2, varscan2
- BHLHE22 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.105); catalogued as rs1375950161; called by muse, mutect2
- C11orf53 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1383160361; called by muse, varscan2
- CHD4 | c.3408C>A p.N1136K (on ENST00000357008 / NM_001363606.2; = p.N1149K on NM_001273.5) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58907527; called by muse, varscan2
- CHST15 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs202236206, COSV60562996; called by muse, mutect2, varscan2
- CRACD | c.2365T>C p.C789R | Missense Mutation (SNP) | VAF 87/344 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99948804; called by muse, mutect2, varscan2
- CRX | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs201969424, COSV55759207; called by muse, mutect2, varscan2
- DLG3 | c.2035C>T p.R679* (on ENST00000374360 / NM_021120.4; = p.R374* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 62/207 reads (30%) | catalogued as COSV99530168; called by muse, mutect2, varscan2
- DUOX2 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs771789022, COSV66531006; called by muse, mutect2
- DYRK1A | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117534, COSV58294108; called by muse, mutect2, varscan2
- FCAR | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as rs191759522; called by muse, mutect2
- FLII | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367938881, COSV57500964; called by muse, mutect2, varscan2
- GLI1 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs754019701, COSV57369377; called by muse, mutect2, varscan2
- GPR176 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1282653299; called by muse, mutect2, varscan2
- HARS2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 32/560 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs752472621, COSV51226807; ClinVar: uncertain significance; called by muse, mutect2
- IRX2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs201989826; called by muse, mutect2, varscan2
- KIF2B | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260059640, COSV52129098; called by muse, mutect2, varscan2
- LHX5 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs1213121764; called by muse, mutect2
- NT5C1B | c.353G>A p.R118H (on ENST00000359846 / NM_001199086.2; = p.R58H on NM_033253.4) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as rs367871143; called by muse, mutect2, varscan2
- PNLIPRP2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782045216, COSV53944274; called by muse, mutect2, varscan2
- POLE | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555227096, COSV100267422, COSV57679936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEC | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 82/660 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.993); catalogued as rs756029134, COSV100743746; called by mutect2, varscan2
- PYHIN1 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 17/143 reads (12%) | catalogued as rs754349350, COSV63721348; called by muse, mutect2, varscan2
- RLN1 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV56346890, COSV56347248; called by muse, mutect2, varscan2
- SHANK2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as rs189053721; called by muse, mutect2, varscan2
- SMC2 | c.3394C>G p.R1132G | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV53956360; called by muse, varscan2
- SMYD3 | c.670C>T p.R224* (on ENST00000490107 / NM_001375962.1; = p.R165* on NM_022743.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/275 reads (24%) | catalogued as rs777672375; called by muse, mutect2, varscan2
- SPRED2 | c.244A>C p.T82P | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs745895241; called by muse, mutect2, varscan2
- SYT1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV54048280; called by muse, mutect2
- TBC1D9 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs761253600; called by muse, mutect2
- TPST2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as rs368243348; called by muse, mutect2, varscan2
- ULBP2 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 83/460 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs149841016; called by muse, mutect2, varscan2
- USP30 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 48/157 reads (31%) | catalogued as rs1189601692; called by muse, mutect2, varscan2
- VIPR2 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368608177; called by muse, mutect2, varscan2
- ZFP3 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 74/391 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs756287600; called by muse, mutect2, varscan2
- ACACA | c.5466T>G p.I1822M | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ADGRB3 | c.2108T>C p.V703A | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, varscan2
- ALMS1 | c.7067C>G p.S2356* | Nonsense Mutation (SNP) | VAF 54/307 reads (18%) | called by muse, mutect2, varscan2
- ANAPC7 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- ANO4 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF9 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ARID1A | c.4742dup p.H1581Qfs*22 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- CFAP65 | c.5726A>G p.Q1909R | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPHA3 | c.1307-1G>T p.X436_splice | Splice Site (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- FAM205A | c.2024_2030dup p.Q677Hfs*55 | Frame Shift Ins (INS) | VAF 26/172 reads (15%) | called by mutect2, varscan2
- FGFR1OP2 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GFM1 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- INTS2 | c.1493dup p.L498Ffs*13 | Frame Shift Ins (INS) | VAF 54/143 reads (38%) | called by mutect2, pindel, varscan2
- LMO3 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LORICRIN | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | PolyPhen benign (0.331); called by muse, mutect2, varscan2
- LTBP4 | c.2869G>A p.A957T (on ENST00000308370 / NM_001042544.1; = p.A920T on NM_003573.2) | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.164); called by muse, mutect2
- LTK | c.2435del p.L812Wfs*4 | Frame Shift Del (DEL) | VAF 27/135 reads (20%) | called by mutect2, pindel, varscan2
- MGAM | c.4012G>A p.D1338N | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO1E | c.926C>G p.A309G | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- NCAPD3 | c.563T>G p.I188S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, varscan2
- OR5A2 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PLEKHM1 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 175/663 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA2 | c.355del p.I119Lfs*53 | Frame Shift Del (DEL) | VAF 84/279 reads (30%) | called by mutect2, pindel, varscan2
- POLR3A | c.1214G>T p.R405M | Missense Mutation (SNP) | VAF 48/407 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PTPN20 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 95/476 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAPGEF4 | c.1567A>C p.N523H | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIBC1 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RRAGD | c.815C>A p.A272E | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX17 | c.403dup p.Y135Lfs*27 | Frame Shift Ins (INS) | VAF 44/158 reads (28%) | called by mutect2, pindel, varscan2
- TEX10 | c.2308_2309dup p.S770Rfs*20 | Frame Shift Ins (INS) | VAF 6/94 reads (6%) | called by mutect2, pindel
- TMEM168 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRANK1 | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TRPM8 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- USP51 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2
- YBX2 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C10orf71 | c.3345C>T p.H1115= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs1321977503; called by muse, mutect2, varscan2
- FAT2 | c.9828C>T p.N3276= | Silent (SNP) | VAF 80/208 reads (38%) | catalogued as rs781258533; called by muse, mutect2, varscan2
- GP5 | c.123G>A p.A41= | Silent (SNP) | VAF 57/207 reads (28%) | catalogued as rs1043497790, COSV55462910; called by muse, mutect2, varscan2
- HOXA3 | c.417C>T p.N139= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs774936035; called by muse, mutect2
- IGLC3 | c.222G>A p.L74= | Silent (SNP) | VAF 36/914 reads (4%) | called by muse, mutect2
- KCTD7 | c.483C>T p.P161= (on ENST00000275532; = p.R175W on NM_153033.5) | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs568539835, COSV99299232; called by muse, mutect2, varscan2
- KDM4B | c.2019C>T p.F673= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV50208955; called by muse, varscan2
- NLRP7 | c.606G>A p.P202= | Silent (SNP) | VAF 58/188 reads (31%) | catalogued as rs182597034, COSV100052382; called by muse, mutect2, varscan2
- PCDHA7 | c.1794C>T p.D598= | Silent (SNP) | VAF 169/443 reads (38%) | called by muse, mutect2, varscan2
- POLD1 | c.2115C>T p.G705= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs777115075; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PPFIA2 | c.2358C>T p.H786= | Silent (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- RUNX1 | c.1140C>T p.Y380= (on ENST00000344691 / NM_001001890.3; = p.Y407= on NM_001754.5) | Silent (SNP) | VAF 63/269 reads (23%) | catalogued as rs914897271, COSV55867536; called by muse, mutect2, varscan2
- SLC44A2 | c.351C>T p.P117= | Silent (SNP) | VAF 123/268 reads (46%) | catalogued as rs150141328; called by muse, mutect2, varscan2
- CARD9 | c.627+39C>G | Intron (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- CTSB | c.447-65dup | Intron (INS) | VAF 72/245 reads (29%) | called by mutect2, pindel, varscan2
- EPHA6 | c.2386+27106G>T | Intron (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- NRG1 | c.701-4903C>A | Intron (SNP) | VAF 53/158 reads (34%) | called by muse, mutect2, varscan2
- PAH | c.441+16G>A | Intron (SNP) | VAF 123/388 reads (32%) | catalogued as rs751195330, COSV61016355; called by muse, mutect2, varscan2
- PLAU | c.-31-28C>G | Intron (SNP) | VAF 213/397 reads (54%) | called by muse, mutect2, varscan2
- RAB40C | chr16:630341 G>A | 3'Flank (SNP) | VAF 18/40 reads (45%) | catalogued as rs1291521600; called by muse, mutect2, varscan2
- RBFOX3 | c.756-100C>T | Intron (SNP) | VAF 26/112 reads (23%) | catalogued as rs1425365608; called by muse, mutect2, varscan2
- SLC17A9 | c.629-47C>T | Intron (SNP) | VAF 61/196 reads (31%) | catalogued as rs751383691; called by muse, mutect2, varscan2
- STX17 | c.190-5316C>G | Intron (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- TBC1D22B | c.-45G>C | 5'UTR (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
